Somatic mutation profile of tumor specimen TCGA-AF-2687-01A (aliquot TCGA-AF-2687-01A-02D-1733-10) from TCGA case TCGA-AF-2687, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 57.8 years (21,098 days).
Specimen TCGA-AF-2687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d36a1041-7c47-4abc-a110-d1efb3b2f4f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2687-10A (Blood Derived Normal), aliquot TCGA-AF-2687-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd60c38-3895-4deb-8a5c-1885c9cc46b8

The open-access MAF lists 119 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 83, Silent 31, Nonsense Mutation 3, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- TERT | c.3329C>T p.T1110M | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as rs199422306, CM072077, COSV57224829; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 110/193 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV57056059; called by muse, mutect2, varscan2
- ACCS | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1053652280, COSV55458186, COSV55459706; called by mutect2, varscan2
- ACE | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.56); catalogued as COSV52009456; called by muse, mutect2, varscan2
- ACSF3 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs200352879, COSV58079644; called by muse, mutect2, varscan2
- ADAMTS5 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV53180827; called by muse, mutect2, varscan2
- ADGRL2 | c.4194G>C p.R1398S (on ENST00000370717 / NM_001366005.1; = p.R1342S on NM_012302.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.103); catalogued as COSV54675567; called by muse, mutect2, varscan2
- AKAP6 | c.6299G>A p.R2100Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs182849819, COSV55229854; called by muse, mutect2, varscan2
- ANO3 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs199929076, COSV56780720; called by muse, mutect2, varscan2
- ARHGAP20 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.137); catalogued as rs760923229, COSV52810148; called by muse, mutect2, varscan2
- ARHGEF18 | c.668C>T p.T223M (on ENST00000359920 / NM_001130955.2; = p.T119M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424662539, COSV60472752; called by muse, mutect2, varscan2
- ARID1A | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1202361373, COSV61384914; called by muse, mutect2, varscan2
- BACH2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57584199; called by muse, mutect2, varscan2
- BRD3 | c.1486_1500del p.E496_K500del | In Frame Del (DEL) | VAF 24/130 reads (18%) | catalogued as rs771963978; called by mutect2, varscan2
- CCDC157 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV53175309; called by muse, mutect2, varscan2
- CDKL1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758484311, COSV53580711; called by muse, mutect2, varscan2
- CFAP45 | c.1349T>A p.L450H | Missense Mutation (SNP) | VAF 120/281 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100928554; called by muse, mutect2, varscan2
- CLEC9A | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100872791; called by mutect2, varscan2
- CORO7 | c.1858C>A p.R620S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs766836793, COSV52031780, COSV99227487; called by muse, mutect2, varscan2
- DAAM1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs570446187, COSV62834410; called by muse, mutect2, varscan2
- DAAM2 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV51352750; called by muse, mutect2, varscan2
- DLL4 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs755422423, COSV51062145; called by muse, mutect2, varscan2
- DNM3 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV62461744; called by muse, mutect2, varscan2
- EEF1B2 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51911253; called by muse, mutect2, varscan2
- FBF1 | c.604G>A p.E202K (on ENST00000586717; = p.E216K on NM_001319193.1) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV59865902; called by muse, mutect2, varscan2
- FMN2 | c.4043T>C p.I1348T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV60432287; called by muse, mutect2, varscan2
- GOLGA5 | c.2113A>G p.M705V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs754197576, COSV99370871; called by muse, mutect2, varscan2
- HSPA14 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV101000656; called by muse, mutect2, varscan2
- IQCB1 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as COSV60437242; called by muse, mutect2
- JADE2 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50920965; called by muse, mutect2, varscan2
- KCNQ3 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 95/289 reads (33%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.727); catalogued as rs1256382316, COSV66475038; called by muse, mutect2, varscan2
- KIAA0895L | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51783605; called by muse, mutect2, varscan2
- KRT38 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs753649036, COSV99878175; called by muse, mutect2, varscan2
- LDOC1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV65159453; called by muse, mutect2, varscan2
- LINGO2 | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV58058964; called by muse, mutect2, varscan2
- LMNB1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99745824; called by muse, mutect2, varscan2
- LRP4 | c.2689A>G p.I897V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as rs773547550, COSV66136916; called by muse, mutect2, varscan2
- LRRC8A | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52187188, COSV52188975; called by muse, mutect2, varscan2
- MAP3K1 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101266591, COSV68125050, COSV99064094; called by muse, mutect2, varscan2
- MAST1 | c.3599G>A p.G1200D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52249893; called by muse, mutect2, varscan2
- MC5R | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs370250614, COSV61254622; called by muse, mutect2
- MRPL32 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV56238175, COSV99034057; called by muse, mutect2, varscan2
- MTMR12 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769772016, COSV53783941; called by muse, mutect2
- NCOA3 | c.1560C>A p.S520R | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59069641; called by muse, mutect2, varscan2
- NMT1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51960812; called by muse, mutect2, varscan2
- NOD2 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56052561; called by muse, mutect2, varscan2
- NOVA1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 176/546 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746531696, COSV57472771; called by muse, mutect2, varscan2
- NOVA2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs754714738, COSV54358585; called by muse, mutect2, varscan2
- NPY5R | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58452698; called by muse, mutect2, varscan2
- ORC5 | c.87C>G p.S29R | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.925); catalogued as rs746696962, COSV99856925; called by muse, mutect2, varscan2
- PAM | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV57209417; called by muse, varscan2
- PCDHA10 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as COSV100254468, COSV56507222; called by muse, mutect2, varscan2
- PDE3A | c.1151A>T p.Q384L | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62976598; called by muse, mutect2, varscan2
- PLCD3 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV59561401; called by muse, mutect2, varscan2
- PRPF38A | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs968173827, COSV57122818; called by muse, mutect2, varscan2
- PRSS38 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs373059773; called by muse, mutect2, varscan2
- PTGFR | c.959G>T p.S320I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV66115748; called by muse, varscan2
- RAB5B | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as rs1333495283, COSV100822119; called by muse, mutect2, varscan2
- RANBP6 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs750553940, COSV52390252; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 30/153 reads (20%) | catalogued as COSV101208251, COSV67760348; called by muse, mutect2, varscan2
- RPF2 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV64369900; called by muse, mutect2, varscan2
- RSBN1L | c.2309A>G p.N770S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV58509375, COSV58510981; called by muse, mutect2, varscan2
- SALL3 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73306175; called by muse, mutect2, varscan2
- SESTD1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144405691; called by muse, mutect2, varscan2
- SKAP1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs368601769; called by muse, mutect2, varscan2
- SLC6A2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758931200, COSV54919131; called by muse, mutect2, varscan2
- SORT1 | c.576T>A p.S192R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV56667840, COSV56670533; called by muse, mutect2, varscan2
- SQSTM1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201239306, CM155582, COSV52974069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STT3A | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs765580288, COSV67065097; called by muse, mutect2, varscan2
- SYT16 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV70858292; called by muse, mutect2, varscan2
- TBX20 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101282372; called by muse, mutect2
- TEX10 | c.175A>C p.I59L | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100887713, COSV100887725; called by muse, mutect2, varscan2
- TKTL2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54918476, COSV54919858, COSV99761244; called by muse, mutect2, varscan2
- TMEM164 | c.540G>C p.Q180H (on ENST00000372068 / NM_032227.4; = p.Q31H on NM_017698.2) | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV55813666; called by muse, mutect2, varscan2
- TOP3A | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58178912; called by muse, mutect2, varscan2
- TRAPPC9 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs190087909; called by muse, mutect2, varscan2
- TSFM | c.668C>T p.A223V (on ENST00000323833 / NM_001172696.2; = p.A202V on NM_005726.6) | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV99142313; called by muse, mutect2, varscan2
- TTN | c.92756G>A p.R30919H (on ENST00000591111; = p.R23495H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/190 reads (11%) | PolyPhen probably damaging (0.998); catalogued as rs775600228, COSV60171802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ULBP3 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66254409; called by muse, mutect2
- WDR37 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1433377878, COSV54129917; called by muse, mutect2, varscan2
- XPNPEP2 | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as COSV64369483; called by muse, mutect2, varscan2
- ZNF354A | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs778848027, COSV59983918; called by muse, mutect2, varscan2
- ZNF536 | c.3728A>T p.D1243V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV62827910, COSV62830978; called by muse, mutect2, varscan2
- ZNF839 | c.3G>A p.M1? (on ENST00000558850 / NM_001267827.1; = p.M117I on NM_018335.5) | Translation Start Site (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV99216176; called by muse, mutect2, varscan2
- SMURF2 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SPATA31A1 | c.2975C>A p.P992H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- AKAP9 | c.4581A>G p.E1527= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100662304; called by muse, mutect2
- AL121899.2 | c.615C>T p.L205= | Silent (SNP) | VAF 81/187 reads (43%) | catalogued as COSV67351331; called by muse, mutect2, varscan2
- ASIC4 | c.783G>A p.P261= | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as rs572070268, COSV61732439; called by muse, mutect2, varscan2
- BPIFB3 | c.804C>T p.A268= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as COSV64957604; called by muse, mutect2, varscan2
- CALB2 | c.438G>A p.P146= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs760026354, COSV56940501; called by muse, mutect2, varscan2
- CDHR5 | c.411G>A p.T137= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as rs140067219; called by muse, mutect2, varscan2
- CHST1 | c.129C>T p.A43= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1564996751, COSV57322126; called by muse, mutect2, varscan2
- COLEC12 | c.1479C>A p.P493= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs770196943, COSV68371585, COSV68371960; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs1369010251, COSV60480151; called by muse, mutect2, varscan2
- EPHA1 | c.723C>T p.P241= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV51972831; called by muse, mutect2, varscan2
- FSD1 | c.330C>T p.S110= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs761135570, COSV55697093; called by muse, mutect2, varscan2
- IL5RA | c.636G>T p.A212= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as COSV99842854; called by muse, mutect2, varscan2
- IMPACT | c.609T>A p.L203= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99408816; called by muse, mutect2, varscan2
- JAKMIP1 | c.1500C>T p.R500= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs149678000; called by muse, mutect2, varscan2
- KCNQ2 | c.1161G>A p.P387= (on ENST00000359125 / NM_172107.4; = p.P377= on NM_004518.6) | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as rs147453497; ClinVar: benign; called by muse, mutect2
- LAMA5 | c.681C>T p.N227= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs1032994376, COSV53356375; called by muse, mutect2, varscan2
- NME8 | c.751C>A p.R251= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs113330102, COSV52252452; called by muse, varscan2
- NRXN1 | c.492C>A p.A164= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV68012172, COSV68024889; called by muse, mutect2, varscan2
- OR10W1 | c.348C>A p.A116= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV67720299, COSV67720600; called by muse, mutect2
- PCDHA9 | c.1923C>T p.D641= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV65326494, COSV65330142; called by muse, mutect2, varscan2
- PEDS1 | c.765C>T p.G255= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs1407353871, COSV59009979; called by muse, mutect2, varscan2
- RAPGEF2 | c.3930A>G p.Q1310= | Silent (SNP) | VAF 96/169 reads (57%) | catalogued as COSV52430444; called by muse, mutect2, varscan2
- SDK1 | c.2610C>T p.T870= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs751835213, COSV67377479; called by muse, mutect2, varscan2
- SLC28A3 | c.1227T>C p.P409= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs770152872, COSV66153998; called by muse, mutect2, varscan2
- SLC2A2 | c.1206A>T p.I402= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV58586916; called by muse, mutect2, varscan2
- SNAPC4 | c.468C>T p.G156= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs766890455, COSV53734785; called by muse, mutect2, varscan2
- TEKT2 | c.1092C>T p.D364= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs775161619, COSV52881395; called by muse, mutect2, varscan2
- TMEM94 | c.88C>T p.L30= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV58597641; called by muse, mutect2, varscan2
- TRIP12 | c.519G>A p.A173= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs570076410, COSV52272259; called by muse, mutect2, varscan2
- UTP20 | c.5014C>T p.L1672= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV55380328; called by muse, mutect2, varscan2
- XRCC1 | c.1767A>G p.E589= | Silent (SNP) | VAF 84/138 reads (61%) | catalogued as COSV53450925; called by muse, mutect2, varscan2
